Gene-level copy-number profile of tumor specimen TCGA-G4-6314-01A from TCGA case TCGA-G4-6314, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.5 years (27,958 days).
Specimen TCGA-G4-6314-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.4354f08c-d05a-4b68-a4fa-d13c9d9ed0f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6314-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/315884c9-e1f1-481b-a81e-afc0f3dfa44e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,375; copy number 2: 8,355; copy number 3: 30,584; copy number 4: 14,589; copy number 5: 1,534; copy number 6: 1,783; copy number 7: 1,027; copy number 8: 245; copy number 10: 74; copy number 13: 122; copy number 14: 25; copy number 18: 33; copy number 19: 39; copy number 25: 9; copy number 33: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-G4-6314-01): tumor purity 0.51, ploidy 3.3, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,585 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:2,129,112–5,678,434, 202 genes, copy number 8–19 (within-gene range 6–19) (broad region; genes not listed).
- chr11:8,391,868–9,067,776, 20 genes, copy number 25–33 (within-gene range 4–33): STK33, AP006442.1, TRIM66, AC091053.2, RPL27A, SNORA3A, SNORA3B, DENND2B, AC091053.1, AC026894.1, RNA5SP330, Y_RNA, AKIP1, C11orf16, ASCL3, Y_RNA, TMEM9B, TMEM9B-AS1, NRIP3, AC079296.1.
- chr11:11,570,084–14,892,231, 60 genes, copy number 7: AC104031.1, MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1.
- chr11:14,907,518–14,907,986, 1 gene, copy number 7: CALCP.
- chr13:18,467,172–81,044,691, 966 genes, copy number 7 (broad region; genes not listed).
- chr16:10,214,784–10,483,638, 5 genes, copy number 18 (within-gene range 3–18): AC022168.1, RN7SL493P, ATF7IP2, AC131649.1, AC131649.2.
- chr16:14,901,499–15,157,020, 25 genes, copy number 14: AC136443.3, MIR3179-1, MIR3670-1, AC138932.1, MIR3180-1, PKD1P3, Y_RNA, NPIPA1, MIR6511A1, MIR6770-1, AC138932.3, PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3, AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1.
- chr16:32,649,193–34,163,110, 85 genes, copy number 13 (broad region; genes not listed).
- chr16:46,469,341–55,833,337, 221 genes, copy number 8–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
